Gene-level copy-number profile of tumor specimen ALCH-ABRW-TTP1-A from ALCHEMIST case ALCH-ABRW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 53.0 years (19,343 days).
Specimen ALCH-ABRW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba9366fe-32e9-4987-b19f-7c5af661495a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABRW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/2cdbc05b-ba8e-4bdb-ad20-6b680bfbc960

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 712; copy number 1: 20,491; copy number 2: 33,258; copy number 3: 3,517; copy number 4: 934.

Homozygous deletions (total copy number 0; autosomes only): 167 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,280,436–1,292,029, 1 gene: SCNN1D.
- chr1:1,296,110–1,296,170, 1 gene (within-gene range 0–1): MIR6726.
- chr1:2,425,980–2,505,532, 3 genes (within-gene range 0–2): PLCH2, AL139246.1, AL139246.4.
- chr2:42,532,766–42,533,442, 1 gene (within-gene range 0–2): AC025750.1.
- chr2:109,732,731–109,737,523, 2 genes: SRSF3P6, RPL22P11.
- chr3:32,730,635–32,737,454, 1 gene: CNOT10-AS1.
- chr3:89,587,886–90,257,415, 5 genes: MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P.
- chr9:61,190,003–61,666,386, 12 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–1): AL357936.1.
- chr9:133,414,358–133,459,402, 1 gene (within-gene range 0–1): ADAMTS13.
- chr10:86,435,256–87,342,612, 33 genes: WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A.
- chr10:92,418,667–92,420,875, 1 gene: MARK2P9.
- chr10:103,608,619–103,610,050, 1 gene (within-gene range 0–1): AL121929.2.
- chr12:34,249,481–34,249,958, 1 gene: AK6P1.
- chr12:131,436,447–131,436,960, 1 gene: AC073578.4.
- chr15:78,749,833–78,898,139, 6 genes: AC022748.3, AC022748.1, ADAMTS7, MORF4L1, AC103975.1, RPL21P116.
- chr16:33,577,502–33,622,547, 1 gene (within-gene range 0–2): AC142384.1.
- chr16:58,705,799–58,706,297, 1 gene: AC012183.1.
- chr16:85,690,084–85,751,129, 5 genes: C16orf74, AC018695.6, AC018695.9, MIR1910, AC018695.2.
- chr16:88,638,572–89,237,141, 35 genes: IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS, TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1, AC135782.2, AC135782.1, ACSF3, AC135782.3, LINC00304, LINC02138, CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–1): AC137932.3.
- chr16:89,490,719–90,222,851, 38 genes (within-gene range 0–1): SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr18:11,618,208–11,639,699, 3 genes: AP001120.4, NPIPB1P, AP001120.2.
- chr19:3,585,478–3,626,815, 4 genes: GIPC3, TBXA2R, CACTIN-AS1, CACTIN.
- chr19:9,019,344–9,126,950, 7 genes: BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
